Somatic mutation profile of tumor specimen TARGET-10-PAPFHH-09A (aliquot TARGET-10-PAPFHH-09A-01D) from TARGET case TARGET-10-PAPFHH, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.9 years (1,795 days).
Specimen TARGET-10-PAPFHH-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e212c912-3356-4e8c-a136-9361fa2c0d2f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPFHH-14A (Bone Marrow Normal), aliquot TARGET-10-PAPFHH-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2e9df517-8fd3-412a-bcba-e5c4b7e07e9a

The open-access MAF lists 30 somatic variants for this specimen: 19 protein-altering or splice-affecting, 8 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 8, Frame Shift Ins 3, Intron 2, RNA 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.37G>C p.G13R | Missense Mutation (SNP) | VAF 16/58 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs121434595, COSV54736386, COSV54736476, COSV54736550; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- NRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 8/58 reads (14%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen possibly damaging (0.541); catalogued as rs121913250, CM136798, COSV54736487, COSV54736621, COSV54736940; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- ABCC12 | c.1844G>A p.R615H | Missense Mutation (SNP) | VAF 33/115 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs547878738, COSV60911544, COSV60913298; called by muse, mutect2, varscan2
- CPXM2 | c.911G>A p.R304H | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.781); catalogued as rs376038492; called by muse, mutect2, varscan2
- GSN | c.241G>A p.V81M | Missense Mutation (SNP) | VAF 41/137 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs376961112; called by muse, mutect2, varscan2
- LFNG | c.574G>A p.G192S (on ENST00000222725 / NM_001040167.2; = p.G63S on NM_002304.2) | Missense Mutation (SNP) | VAF 44/96 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.85); catalogued as rs375889285, COSV99761689; called by muse, mutect2, varscan2
- PCDHAC1 | c.2159G>A p.R720H | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV53839791; called by muse, mutect2, varscan2
- SIM1 | c.220G>T p.D74Y | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV53494937; called by muse, mutect2, varscan2
- SLC22A12 | c.334G>A p.D112N | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0.387); catalogued as rs772733867, COSV60574404; called by muse, mutect2, varscan2
- SNX15 | c.286C>T p.R96W | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs150770183; called by muse, mutect2, varscan2
- THBS2 | c.1619G>A p.R540H | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs757643418, COSV64677996; called by muse, mutect2
- ZBTB4 | c.1055G>A p.R352H | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1210442686, COSV104410173; called by muse, mutect2, varscan2
- ZNF629 | c.2339G>A p.R780H | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.101); catalogued as rs773610715, COSV52698036; called by muse, mutect2, varscan2
- ACAT1 | c.403dup p.M135Nfs*42 | Frame Shift Ins (INS) | VAF 56/205 reads (27%) | called by mutect2, pindel, varscan2
- ASXL3 | c.1730C>A p.S577Y | Missense Mutation (SNP) | VAF 73/247 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- HMG20A | c.64_79del p.E22Lfs*5 | Frame Shift Del (DEL) | VAF 16/70 reads (23%) | called by mutect2, pindel*, varscan2
- IKZF1 | c.370_371insG p.I124Sfs*76 | Frame Shift Ins (INS) | VAF 39/99 reads (39%) | called by mutect2, pindel, varscan2
- RASA3 | c.2314G>A p.D772N | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- ZNF507 | c.2420_2421insGACCA p.H808Tfs*14 | Frame Shift Ins (INS) | VAF 33/155 reads (21%) | called by mutect2, pindel, varscan2
- AHNAK2 | c.690G>A p.T230= | Silent (SNP) | VAF 15/79 reads (19%) | catalogued as rs779805398, COSV60912200; called by muse, mutect2, varscan2
- ALPK2 | c.3006C>A p.T1002= | Silent (SNP) | VAF 73/238 reads (31%) | catalogued as rs1457163574; called by muse, mutect2, varscan2
- C1orf167 | c.3876C>T p.P1292= | Silent (SNP) | VAF 9/46 reads (20%) | called by muse, mutect2, varscan2
- CDH23 | c.5022C>T p.I1674= | Silent (SNP) | VAF 33/106 reads (31%) | catalogued as rs376952695; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- KCNJ13 | c.855G>A p.R285= | Silent (SNP) | VAF 11/196 reads (6%) | called by muse, mutect2
- LTN1 | c.4059C>T p.I1353= | Silent (SNP) | VAF 17/197 reads (9%) | called by muse, mutect2
- OR2W3 | c.90C>A p.V30= | Silent (SNP) | VAF 25/192 reads (13%) | called by muse, mutect2, varscan2
- WWC3 | c.3273C>T p.D1091= | Silent (SNP) | VAF 32/220 reads (15%) | catalogued as rs759693240; called by muse, mutect2, varscan2
- CCSER1 | c.1509+12555C>T | Intron (SNP) | VAF 24/109 reads (22%) | catalogued as rs1445584800; called by muse, mutect2, varscan2
- LINC02312 | n.697C>T | RNA (SNP) | VAF 5/20 reads (25%) | called by muse, mutect2, varscan2
- NFE2 | c.-56-72C>T | Intron (SNP) | VAF 4/24 reads (17%) | called by muse, mutect2
